Somatic mutation profile of tumor specimen BA2963D (aliquot aq-BA2963D) from BEATAML1.0 case 2204, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Atypical chronic myeloid leukemia, BCR/ABL negative; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.6 years (17,394 days).
Specimen BA2963D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 165d1094-1aa2-4ed4-a8ec-760cd266d30a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2028D (Solid Tissue Normal), aliquot aq-BA2028D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c48a0c24-b5a1-4746-b575-1d6209cd53ce

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAHCC1 | c.4814G>A p.R1605H | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs370431109; called by muse, mutect2, varscan2
- CACNA2D4 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs754788510, COSV54959895; called by muse, mutect2, varscan2
- FAM189A2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs139318995; called by muse, varscan2
- STK32B | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as rs367898855, COSV51497036; called by muse, mutect2, varscan2
- DNAH1 | c.4714C>A p.H1572N | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2
- KANSL1 | c.723del p.L242Ffs*37 | Frame Shift Del (DEL) | VAF 38/210 reads (18%) | called by mutect2, pindel, varscan2
- PHACTR4 | c.1556A>C p.E519A (on ENST00000373839 / NM_001350159.2; = p.E529A on NM_023923.4) | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SUZ12 | c.1850G>A p.W617* | Nonsense Mutation (SNP) | VAF 52/157 reads (33%) | called by muse, mutect2, varscan2
- TET2 | c.1469_1472dup p.Q491Hfs*14 | Frame Shift Ins (INS) | VAF 30/96 reads (31%) | called by mutect2, varscan2
- CSPG5 | c.567A>G p.P189= | Silent (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- ZNF736 | c.1185A>G p.K395= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as COSV61908885; called by muse, mutect2, varscan2
- NPHP4 | c.3316-122C>T | Intron (SNP) | VAF 19/53 reads (36%) | catalogued as rs1047346841; called by muse, mutect2, varscan2
